Gene-level copy-number profile of tumor specimen TCGA-V5-A7RC-06A from TCGA case TCGA-V5-A7RC, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; Tumor grade: GX; Age at diagnosis: 56.0 years (20,439 days).
Specimen TCGA-V5-A7RC-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.61c5836e-9637-4103-8f0d-260c0dbbccfb.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-V5-A7RC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 411 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/12854ae8-b4f1-4c5a-8d9a-f1ce726b8a5e

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 506; copy number 1: 2,393; copy number 2: 10,878; copy number 3: 16,005; copy number 4: 22,390; copy number 5: 3,454; copy number 6: 1,884; copy number 7: 204; copy number 8: 172; copy number 9: 103; copy number 10: 155; copy number 11: 58; copy number 12: 314; copy number 13: 1,459; copy number 14: 24; copy number 15: 46; copy number 17: 5; copy number 18: 19; copy number 20: 18; copy number 21: 97; copy number 25: 18; copy number 90: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-V5-A7RC-06A-11D-A402-01): tumor purity 0.49, ploidy 3.63, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:105,620,506–105,673,314, 7 genes: IGHG4, MIR8071-1, IGHG2, MIR8071-2, COPDA1, IGHGP, ELK2AP.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,326 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:39,799,422–40,876,670, 46 genes, copy number 9–90 (within-gene range 5–90): AL033527.3, LINC02811, TRIT1, Y_RNA, MYCL, MYCL-AS1, Y_RNA, MFSD2A, AL663070.1, CAP1, PPT1, OAZ1P1, RLF, RNU6-1237P, TMCO2, AL050341.2, ZMPSTE24, AL050341.1, COL9A2, AL031985.2, SMAP2, AL031985.1, AL031985.4, ZFP69B, AL031985.3, AL603839.4, ZFP69, AL603839.3, EXO5, AL603839.1, AL603839.2, ZNF684, AL356379.2, AL356379.1, GTF2F2P2, RIMS3, AL031289.2, AL031289.1, NFYC-AS1, NFYC, MIR30E, MIR30C1, KCNQ4, RN7SL326P, CITED4, AC119677.1.
- chr2:88,811,186–88,861,563, 1 gene, copy number 12 (within-gene range 4–12): AC244205.1.
- chr2:88,857,161–89,960,754, 67 genes, copy number 12 (broad region; genes not listed).
- chr3:93,843,764–198,222,513, 1,800 genes, copy number 9–13 (broad region; genes not listed).
- chr6:40,271,566–45,664,349, 167 genes, copy number 9–21 (broad region; genes not listed).
- chr11:69,294,151–71,821,548, 74 genes, copy number 9–14 (within-gene range 4–14) (broad region; genes not listed).
- chr11:72,519,986–72,843,674, 19 genes, copy number 12: ART2P, AP005019.2, AP005019.1, LINC01537, PDE2A, PDE2A-AS2, MIR139, RNU7-105P, PDE2A-AS1, ARAP1, ARAP1-AS1, AP003065.1, ARAP1-AS2, RPS12P20, STARD10, Y_RNA, MIR4692, AP002381.2, ATG16L2.
- chr12:8,390,270–8,428,610, 5 genes, copy number 18: AC092865.4, AC092865.3, AC092865.2, OR7E140P, OR7E148P.
- chr12:66,023,620–70,637,440, 101 genes, copy number 15–25 (within-gene range 7–25) (broad region; genes not listed).
- chr19:58,278,955–58,605,223, 45 genes, copy number 11 (within-gene range 6–11): ZNF8, ZNF8-ERVK3-1, ERVK3-1, AC010642.2, AC010642.1, ZSCAN22, MIR6806, A1BG, AC012313.3, A1BG-AS1, AC012313.10, ZNF497, AC012313.2, AC012313.6, RNA5SP473, ZNF837, RPS5, MIR4754, RNF225, LINC02560, ZNF584, AC012313.1, AC012313.4, AC012313.5, ZNF132, AC012313.8, ZNF324B, ZNF324, ZNF446, AC012313.7, SLC27A5, RNU6-1337P, RN7SL693P, AC012313.9, ZBTB45, RN7SL525P, TRIM28, MIR6807, CHMP2A, UBE2M, MZF1-AS1, MZF1, CENPBD1P1, AC016629.3, AC016629.1.
- chr22:26,006,389–26,006,532, 1 gene, copy number 11: Z98949.1.

Autosomal genes at a single copy (total copy number 1): 6. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
